Gene-level copy-number profile of tumor specimen TCGA-N7-A59B-01A from TCGA case TCGA-N7-A59B, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Age at diagnosis: 69.4 years (25,360 days).
Specimen TCGA-N7-A59B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.072e3a55-a5ac-4fb9-8617-8aa5fb129076.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-N7-A59B-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cc5170b4-6188-43bc-b8a8-ac83e591f09c

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 2: 289; copy number 3: 10,383; copy number 4: 19,904; copy number 5: 540; copy number 6: 24,748; copy number 7: 202; copy number 8: 484; copy number 9: 1,889; copy number 10: 240; copy number 11: 226; copy number 12: 4; copy number 13: 585; copy number 14: 225; copy number 15: 1; copy number 17: 35; copy number 18: 7; copy number 24: 10; copy number 26: 13; copy number 27: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-N7-A59B-01A-11D-A28Q-01): tumor purity 0.9, ploidy 3.48, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:78,550,739–78,553,296, 1 gene: AC046158.3.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 902 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–11,827,409, 206 genes, copy number 14 (within-gene range 11–14) (broad region; genes not listed).
- chr2:17,539,126–17,817,798, 4 genes, copy number 27 (within-gene range 11–27): VSNL1, SMC6, GEN1, MSGN1.
- chr2:18,040,606–18,040,733, 1 gene, copy number 27: AC079802.1.
- chr2:20,239,892–20,679,243, 16 genes, copy number 17: DRG1P1, RNU7-113P, PUM2, SLC7A15P, RNA5SP86, RHOB, AC023137.1, Y_RNA, AC012065.1, NDUFAF2P1, HS1BP3, AC012065.2, HS1BP3-IT1, RPS25P3, GDF7, AC012065.3.
- chr2:67,562,067–68,110,948, 6 genes, copy number 13: LINC02831, AC007422.1, AC010987.1, LINC01812, FBXL12P1, C1D.
- chr3:168,094,049–198,222,513, 599 genes, copy number 13–27 (broad region; genes not listed).
- chr5:50,396,192–50,443,248, 1 gene, copy number 15 (within-gene range 2–15): EMB.
- chr5:126,179,565–126,509,021, 4 genes, copy number 18: LINC02039, GRAMD2B, AC093535.1, AC093535.2.
- chr5:155,397,291–155,493,598, 2 genes, copy number 26: AC010591.1, AC008725.1.
- chr10:60,869,438–62,304,033, 12 genes, copy number 14 (within-gene range 6–14): RHOBTB1, RNU2-72P, LINC00845, TMEM26, TMEM26-AS1, AL356952.1, CABCOCO1, AL451049.1, LINC02625, ARID5B, RTKN2, LINC02621.
- chr17:39,461,486–39,747,291, 14 genes, copy number 18–26 (within-gene range 3–26): CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7.
- chr17:78,066,258–78,278,492, 16 genes, copy number 13: UBE2V2P2, RNU6-625P, TMC6, TMC8, C17orf99, EIF5AP2, SYNGR2, TK1, AFMID, AC087645.1, BIRC5, TMEM235, AC087645.4, THA1P, AC087645.3, LINC01993.
- chr19:15,049,480–15,419,141, 19 genes, copy number 17 (within-gene range 9–17): CASP14, OR1I1, SYDE1, ILVBL, AC003956.1, OR10B1P, RNU6-782P, NOTCH3, MIR6795, AC004257.1, EPHX3, BRD4, AC005776.1, AC005776.2, AKAP8, AC005785.1, AKAP8L, AC005785.2, AC006128.1.
- chr20:10,996,293–11,029,455, 1 gene, copy number 14 (within-gene range 6–14): LINC02871.
- chr20:11,234,170–11,301,525, 1 gene, copy number 14: AL049649.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
